TCGA case TCGA-ZB-A96V — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Thoraxklinik. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50072717-861c-4b60-b595-d8ea23bb1c67

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Thymic carcinoma, NOS: ICD-O-3 morphology code: 8586/3; ICD-10 code: C38.1; Tissue or organ of origin: Anterior mediastinum; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 44.5 years (16,245 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IVb; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 932 days (2.6 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 58 days; Days to treatment end: 94 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 259 days; Disease response: Tumor Free.
- Days to follow up: 932 days (2.6 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 96 kg; Height: 185 cm; BMI: 28.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZB-A96V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-ZB-A96V-01A-01-TS1: Section location: Top; Percent tumor cells: 42; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 55; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-ZB-A96V-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZB-A96V-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: IVb.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type C.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 932 days; disease-specific survival: no event (censored), 932 days; progression-free interval: no event (censored), 932 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZB-A96V-01A-11D-A427-01): tumor purity 0.46, ploidy 2.12, whole-genome doublings 0.
